Somatic mutation profile of tumor specimen C3N-03027-01 (aliquot CPT0226390006) from CPTAC case C3N-03027, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 65.4 years (23,896 days).
Specimen C3N-03027-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 564f5c0a-3d98-48d8-9de1-9afb90201c12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03027-31 (Blood Derived Normal), aliquot CPT0226430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6aa81131-69f9-47e1-ae76-c407dfd4ab69

The open-access MAF lists 160 somatic variants for this specimen: 99 protein-altering or splice-affecting, 43 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 43, Intron 11, Nonsense Mutation 5, Splice Site 4, Splice Region 3, 3'UTR 3, 5'UTR 2, RNA 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 35/159 reads (22%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AC006059.2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs531535524; called by muse, mutect2, varscan2
- AGPAT4 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs577233526; called by muse, mutect2
- AQP4 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 45/345 reads (13%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs1405904864; called by muse, mutect2, varscan2
- ARHGAP39 | c.1069C>T p.L357F | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV52770290; called by muse, mutect2, varscan2
- C7orf31 | c.1464T>A p.S488R | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1264283985; called by muse, mutect2, varscan2
- C8orf34 | c.1166T>G p.F389C | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV57414892; called by muse, mutect2
- CACNA1H | c.1833G>A p.M611I | Missense Mutation (SNP) | VAF 40/383 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV62002723; called by muse, mutect2
- CEACAM21 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 188/462 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.18); catalogued as rs201857878; called by muse, mutect2, varscan2
- CFAP92 | c.1729C>A p.H577N | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as rs1417821510; called by muse, mutect2, varscan2
- CRYBG1 | c.2728G>A p.G910R | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs549196715; called by muse, mutect2
- DGKB | c.32G>T p.S11I | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV51775278; called by muse, mutect2, varscan2
- DNAH5 | c.9139G>A p.E3047K | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54206416; called by muse, mutect2, varscan2
- DOCK1 | c.3647A>G p.Y1216C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99039993; called by muse, mutect2, varscan2
- EHBP1L1 | c.3884C>T p.S1295L | Missense Mutation (SNP) | VAF 118/1035 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as rs992449265; called by muse, mutect2, varscan2
- ERBB4 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as rs1438732641, COSV61477133; called by muse, mutect2, varscan2
- FAM181B | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.244); catalogued as rs1213670452; called by muse, mutect2
- FBLN5 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 130/556 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50907232; called by muse, mutect2, varscan2
- FHAD1 | c.115C>T p.H39Y | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1427653656; called by mutect2, varscan2
- IFIT2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs532385968; called by muse, mutect2
- IGSF10 | c.106T>C p.Y36H | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs1365109350; called by muse, mutect2
- KLF10 | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs745923868; called by muse, mutect2, varscan2
- KLHL24 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.487); catalogued as rs547446710, COSV54425693; called by muse, mutect2
- KRT4 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 56/399 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs772882487, COSV53405585; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMA2 | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 40/413 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV70344837, COSV70353136; called by muse, mutect2, varscan2
- LAMC3 | c.3272G>A p.R1091Q | Missense Mutation (SNP) | VAF 72/569 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as rs376158532, COSV100735905; called by muse, mutect2, varscan2
- LLGL2 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 61/484 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as rs769075767; called by muse, mutect2, varscan2
- LRP1B | c.10261G>A p.D3421N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.04); catalogued as rs565672182; called by muse, mutect2, varscan2
- LRP6 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 44/435 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.034); catalogued as rs1397330487; called by muse, mutect2
- MAN1A1 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63787171; called by mutect2, varscan2
- MYBPC1 | c.3118G>A p.D1040N (on ENST00000550270 / NM_206820.2; = p.D1047N on NM_002465.4) | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100638273; called by muse, mutect2, varscan2
- NSL1 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 41/468 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752252376; called by muse, mutect2
- PCDHGA3 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 142/468 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.286); catalogued as COSV54030469; called by muse, mutect2, varscan2
- PCLO | c.6475C>A p.H2159N | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV61621777; called by muse, mutect2, varscan2
- PGBD4 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.908); catalogued as rs1363879160; called by muse, mutect2, varscan2
- PIDD1 | c.1976C>T p.T659M | Missense Mutation (SNP) | VAF 118/421 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.066); catalogued as rs146461213; called by muse, mutect2, varscan2
- PLEKHA8 | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs950425344, COSV99321287; called by muse, mutect2
- PLXNA3 | c.1693G>A p.V565M | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs782421628; called by muse, mutect2, varscan2
- PTGER2 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.09); catalogued as rs1349649651; called by muse, mutect2
- PTPN12 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50370920; called by muse, mutect2, varscan2
- RTL1 | c.3373C>T p.R1125* | Nonsense Mutation (SNP) | VAF 30/306 reads (10%) | catalogued as rs1288248204, COSV101128508; called by muse, mutect2
- SBK2 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 158/478 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs770246844, COSV100705164; called by muse, mutect2, varscan2
- SOX5 | c.1564A>G p.M522V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758550572, COSV58625638; called by muse, mutect2, varscan2
- SULF2 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.986); catalogued as rs1349856840; called by muse, mutect2, varscan2
- TBC1D30 | c.1129G>A p.V377I (on ENST00000542120; = p.V214I on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as rs574681444, COSV57484654; called by muse, mutect2, varscan2
- THSD7A | c.2635C>G p.Q879E | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.084); catalogued as CM124527; called by muse, mutect2
- TTN | c.36479G>A p.S12160N (on ENST00000591111; = p.S4736N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | PolyPhen benign (0); catalogued as rs757590541, COSV100604315; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBE2C | c.102-2A>T p.X34_splice | Splice Site (SNP) | VAF 31/252 reads (12%) | catalogued as COSV54754948; called by muse, mutect2, varscan2
- USH1C | c.1625del p.P542Qfs*8 | Frame Shift Del (DEL) | VAF 36/209 reads (17%) | catalogued as rs754257195; called by mutect2, pindel, varscan2
- ZNF34 | c.638A>G p.H213R | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs753316047; called by muse, mutect2, varscan2
- ZNF91 | c.2719G>T p.E907* | Nonsense Mutation (SNP) | VAF 18/182 reads (10%) | catalogued as COSV56088933; called by muse, mutect2
- ASPM | c.6613C>T p.Q2205* | Nonsense Mutation (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- CKLF-CMTM1 | c.219G>A p.W73* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2
- CNOT6L | c.1112A>T p.K371M (on ENST00000504123 / NM_001286790.2; = p.K366M on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/290 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COBL | c.1407-5C>A | Splice Region (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- DST | c.96A>T p.E32D | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- EFCAB7 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EIF2B3 | c.1235A>T p.N412I | Missense Mutation (SNP) | VAF 47/370 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- EIF3B | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- EPRS1 | c.3301G>A p.V1101I | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERCC4 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.851); called by muse, mutect2
- EVI5L | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- FIZ1 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 178/579 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GAS7 | c.380C>A p.P127Q (on ENST00000432992 / NM_201433.2; = p.P67Q on NM_201432.2) | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- HEPH | c.3173C>T p.T1058I (on ENST00000343002; = p.T791I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- HSF2 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- INTS2 | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.715); called by muse, mutect2
- JAG2 | c.3545A>T p.D1182V | Missense Mutation (SNP) | VAF 156/614 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- KRT74 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 24/666 reads (4%) | called by muse, mutect2
- LDLRAP1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2
- LMTK3 | c.2052G>T p.E684D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MACF1 | c.12118C>A p.Q4040K (on ENST00000372915; = p.Q1973K on NM_012090.5) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- MAP1A | c.6727C>T p.L2243F | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- MAP3K12 | c.2272G>T p.D758Y | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); called by muse, varscan2
- NEGR1 | c.410-1G>A p.X137_splice | Splice Site (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- NKX1-1 | c.967G>T p.V323L | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2
- NKX2-2 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- NRP1 | c.2172C>A p.F724L | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NSD2 | c.3516G>A p.G1172= | Splice Region (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- OTOP2 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 107/378 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PA2G4 | c.427A>G p.I143V | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PAPPA2 | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PARP6 | c.1442A>T p.H481L | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCDHB13 | c.920_922del p.Q307del | In Frame Del (DEL) | VAF 21/209 reads (10%) | called by pindel, varscan2
- PIEZO2 | c.2118G>A p.M706I | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.39); called by muse, mutect2
- PTPRD | c.1765T>A p.S589T | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- RLF | c.4314A>G p.I1438M | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMIM29 | c.184-2A>T p.X62_splice (on ENST00000394990 / NM_001008704.3; = p.X82_splice on NM_178508.5) | Splice Site (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- SOCS5 | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPANXB1 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 186/1049 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- TCF20 | c.4760G>A p.R1587K | Missense Mutation (SNP) | VAF 73/417 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TESK1 | c.507_513del p.K169Nfs*12 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- TMC4 | c.1342C>T p.L448F (on ENST00000617472 / NM_001145303.3; = p.L442F on NM_144686.4) | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNF | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 75/359 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC28 | c.2878T>A p.Y960N | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VPS13C | c.449-2A>G p.X150_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- WDR5 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZFHX2 | c.5203T>A p.L1735I | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- ZNF480 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADI1 | c.303C>T p.G101= | Silent (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- AP3B2 | c.1581C>A p.A527= | Silent (SNP) | VAF 34/354 reads (10%) | called by muse, mutect2
- BIRC6 | c.4344C>T p.V1448= | Silent (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- C1orf94 | c.1663C>A p.R555= (on ENST00000488417 / NM_001134734.2; = p.R365= on NM_032884.5) | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV64916056; called by muse, mutect2, varscan2
- CBLIF | c.816C>T p.L272= | Silent (SNP) | VAF 72/293 reads (25%) | catalogued as COSV57238249; called by muse, mutect2, varscan2
- CCDC59 | c.33G>A p.R11= | Silent (SNP) | VAF 36/271 reads (13%) | called by muse, mutect2, varscan2
- COL6A5 | c.7212G>A p.L2404= (on ENST00000312481; = p.L2400= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/261 reads (24%) | catalogued as COSV55209673; called by muse, mutect2, varscan2
- CRAMP1 | c.1068C>T p.S356= | Silent (SNP) | VAF 51/397 reads (13%) | called by muse, mutect2, varscan2
- CRTAM | c.951G>A p.V317= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- DCAF16 | c.336A>G p.E112= | Silent (SNP) | VAF 47/194 reads (24%) | called by muse, mutect2, varscan2
- FAM50B | c.637C>T p.L213= | Silent (SNP) | VAF 17/226 reads (8%) | called by muse, mutect2
- FSIP2 | c.3270C>T p.D1090= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- HAO2 | c.201G>A p.E67= | Silent (SNP) | VAF 38/174 reads (22%) | called by muse, mutect2, varscan2
- IQGAP3 | c.2766G>A p.L922= | Silent (SNP) | VAF 31/181 reads (17%) | called by muse, mutect2, varscan2
- ITGAV | c.1200A>G p.K400= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV53711579; called by muse, mutect2, varscan2
- ITGAX | c.63C>T p.N21= | Silent (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- ITPR1 | c.324G>A p.R108= | Silent (SNP) | VAF 8/189 reads (4%) | called by muse, mutect2
- IZUMO3 | c.381C>T p.F127= | Silent (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- MAGEC1 | c.2067G>C p.L689= | Silent (SNP) | VAF 42/67 reads (63%) | called by muse, mutect2, varscan2
- MRC1 | c.2016G>A p.T672= | Silent (SNP) | VAF 11/152 reads (7%) | catalogued as rs952345306; called by muse, mutect2
- MUC5B | c.12228C>T p.T4076= | Silent (SNP) | VAF 153/606 reads (25%) | catalogued as rs567071644, COSV101500019, COSV71592184; called by muse, mutect2, varscan2
- NEGR1 | c.555A>G p.G185= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs1557617835; called by muse, mutect2, varscan2
- NEURL4 | c.4011C>T p.C1337= | Silent (SNP) | VAF 38/344 reads (11%) | called by muse, mutect2
- NOL12 | c.597C>T p.A199= | Silent (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- NOL9 | c.1320A>G p.K440= | Silent (SNP) | VAF 15/207 reads (7%) | catalogued as rs1299009466; called by muse, mutect2
- OPRD1 | c.780G>A p.T260= | Silent (SNP) | VAF 16/229 reads (7%) | catalogued as COSV52380462; called by muse, mutect2
- PARP12 | c.768A>G p.K256= | Silent (SNP) | VAF 26/181 reads (14%) | catalogued as rs570229056; called by muse, mutect2, varscan2
- PDHX | c.192G>T p.L64= | Silent (SNP) | VAF 36/242 reads (15%) | called by muse, varscan2
- PPP2CB | c.531G>A p.L177= | Silent (SNP) | VAF 10/281 reads (4%) | called by muse, mutect2
- RAI1 | c.1266C>T p.L422= | Silent (SNP) | VAF 103/381 reads (27%) | catalogued as rs777325097, COSV55390229; called by muse, mutect2, varscan2
- RET | c.3258G>C p.G1086= | Silent (SNP) | VAF 26/378 reads (7%) | called by muse, mutect2
- RSBN1L | c.1377A>G p.R459= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs541751424; called by muse, mutect2, varscan2
- RTL1 | c.1665G>A p.L555= | Silent (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- RTL10 | c.99G>A p.A33= | Silent (SNP) | VAF 40/346 reads (12%) | catalogued as rs768559016; called by muse, mutect2, varscan2
- RTL4 | c.600T>C p.D200= | Silent (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- SPEG | c.8202C>T p.N2734= | Silent (SNP) | VAF 72/304 reads (24%) | catalogued as rs754183008, COSV56676460; called by muse, mutect2, varscan2
- TM6SF1 | c.42C>G p.L14= | Silent (SNP) | VAF 29/546 reads (5%) | catalogued as COSV51943256, COSV51946983; called by muse, mutect2
- TMEM67 | c.885T>G p.P295= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV100019014; called by muse, mutect2, varscan2
- TMPRSS2 | c.804C>A p.P268= | Silent (SNP) | VAF 42/381 reads (11%) | called by muse, mutect2, varscan2
- TOPORS | c.2199G>A p.Q733= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs770356888; called by muse, mutect2, varscan2
- TRPM2 | c.3033C>T p.S1011= | Silent (SNP) | VAF 38/297 reads (13%) | catalogued as rs376292870; called by muse, mutect2, varscan2
- ZNF780B | c.1453C>T p.L485= | Silent (SNP) | VAF 61/146 reads (42%) | called by muse, mutect2, varscan2
- ZXDA | c.1266C>T p.C422= | Silent (SNP) | VAF 50/210 reads (24%) | called by muse, mutect2, varscan2
- AC073316.1 | n.251C>T | RNA (SNP) | VAF 30/235 reads (13%) | catalogued as rs1411267350; called by muse, mutect2, varscan2
- ACOX1 | c.431-2787G>T | Intron (SNP) | VAF 42/325 reads (13%) | called by muse, mutect2, varscan2
- ADA2 | c.753+3964T>G | Intron (SNP) | VAF 38/224 reads (17%) | called by muse, mutect2, varscan2
- ATP7B | c.3557-37A>G | Intron (SNP) | VAF 101/397 reads (25%) | catalogued as rs745767372; called by muse, mutect2, varscan2
- CA13 | c.38-916G>A | Intron (SNP) | VAF 10/73 reads (14%) | catalogued as rs776630390; called by muse, mutect2, varscan2
- DEPDC5 | c.1082-17G>T | Intron (SNP) | VAF 26/138 reads (19%) | called by mutect2, varscan2
- GDAP1L1 | c.*485G>T | 3'UTR (SNP) | VAF 51/191 reads (27%) | called by muse, mutect2, varscan2
- GLYATL1 | n.202A>T | RNA (SNP) | VAF 39/305 reads (13%) | called by muse, mutect2, varscan2
- INO80 | c.3049-2195G>T | Intron (SNP) | VAF 39/248 reads (16%) | called by muse, mutect2, varscan2
- KLHL29 | c.940+73C>T | Intron (SNP) | VAF 22/170 reads (13%) | catalogued as rs987061604; called by muse, mutect2, varscan2
- LHX3 | c.252-56C>T | Intron (SNP) | VAF 39/369 reads (11%) | called by muse, mutect2, varscan2
- ME3 | c.183+23G>A | Intron (SNP) | VAF 30/319 reads (9%) | called by muse, mutect2
- PAK1 | c.*90T>C | 3'UTR (SNP) | VAF 86/246 reads (35%) | called by muse, mutect2, varscan2
- PAK1 | c.*89C>T | 3'UTR (SNP) | VAF 86/246 reads (35%) | called by muse, mutect2, varscan2
- PEX5L | c.-8G>A | 5'UTR (SNP) | VAF 11/294 reads (4%) | catalogued as COSV99828435; called by muse, mutect2
- PISD | c.322-3861C>T | Intron (SNP) | VAF 32/340 reads (9%) | catalogued as rs367554468; called by muse, mutect2
- PLEKHG4B | c.1419+27C>T | Intron (SNP) | VAF 51/688 reads (7%) | catalogued as rs774036259; called by muse, mutect2
- RYR1 | c.-26G>T | 5'UTR (SNP) | VAF 32/290 reads (11%) | called by muse, varscan2
